Somatic mutation profile of tumor specimen MP2PRT-PARXJU-TMP1-A (aliquot MP2PRT-PARXJU-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARXJU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,533 days).
Specimen MP2PRT-PARXJU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c090ff7f-ab88-4e0c-a67b-f6f4074f5b8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXJU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXJU-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35744aae-1eb5-4ac9-aa37-14f2aba21e77

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 28/114 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- DOP1B | c.3583G>A p.D1195N | Missense Mutation (SNP) | VAF 147/514 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1401993090; called by muse, varscan2
- HKDC1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 110/397 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs200115968; called by muse, mutect2, varscan2
- HMCN1 | c.14258C>T p.P4753L | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV54889541; called by muse, mutect2, varscan2
- PCDHB4 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 38/1289 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1319239395; called by muse, mutect2
- PPP4R1 | c.2424G>A p.M808I (on ENST00000400556 / NM_001042388.3; = p.M791I on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/395 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1361288479; called by muse, mutect2, varscan2
- PSMB4 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 118/410 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.272); catalogued as rs143739858; called by muse, mutect2, varscan2
- CACNA1B | c.4327G>A p.A1443T | Missense Mutation (SNP) | VAF 145/457 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- LRP2 | c.3786G>T p.E1262D | Missense Mutation (SNP) | VAF 155/500 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LTBP1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 258/857 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); called by muse, varscan2
- NLRP9 | c.2446G>T p.V816L | Missense Mutation (SNP) | VAF 128/397 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- SETD1A | c.4950G>T p.T1650= | Splice Region (SNP) | VAF 115/349 reads (33%) | called by muse, varscan2
- SETD2 | c.5471T>A p.I1824N | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNN3 | c.138G>A p.A46= | Silent (SNP) | VAF 82/735 reads (11%) | catalogued as COSV55212519; called by muse, varscan2
